TCGA case TCGA-BK-A0CB — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/59e9029a-8ddd-4447-b35a-72bc39f82a30

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 60.0 years (21,930 days); Year of diagnosis: 2010; Method of diagnosis: Incisional Biopsy; FIGO stage: Stage IIIC; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,092 days (3.0 years).
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 2; Lymph nodes tested: 8.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 76.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 13.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 37 days; Days to treatment end: 160 days; Number of cycles: 6; Treatment dose: 3,216 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Treatment intent type: Adjuvant; Days to treatment start: 37 days; Days to treatment end: 160 days; Number of cycles: 6; Treatment dose: 900 mg; Prescribed dose: 150; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded, whether given is unknown: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 189 days; Disease response: Tumor Free.
- Days to follow up: 1,092 days (3.0 years); Disease response: Tumor Free.
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Menopause status: Postmenopausal; Number of pregnancies: 0; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Diabetes, NOS / Hypertension.
- Timepoint category: Initial Diagnosis; Weight: 111 kg; Height: 154 cm; BMI: 46.8.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BK-A0CB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 450 mg.
  Slide TCGA-BK-A0CB-01A-03-BS3: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 15; Percent necrosis: 1; Percent stromal cells: 14; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
  Slide TCGA-BK-A0CB-01A-02-BS2: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-BK-A0CB-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BK-A0CB-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-BK-A0CB-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 420 mg.
  Slide TCGA-BK-A0CB-11A-02-TS2: Section location: Top; Percent tumor cells: 0; Percent normal cells: 100; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-BK-A0CB-11A-04-TS4: Section location: Top; Percent tumor cells: 0; Percent normal cells: 100; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-BK-A0CB-11A-03-TS3: Section location: Top; Percent tumor cells: 0; Percent normal cells: 100; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Surgical approach at diagnosis: open.
- Follow-up form 1: Hypertension diagnosis: Yes; Diabetes diagnosis indicator: Yes; Pregnancies full term count: 0; History colorectal cancer: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free.
- Follow-up form 2: Lost to follow-up: No; Hypertension diagnosis: Yes; Diabetes diagnosis indicator: Yes; Pregnancies full term count: 0; History colorectal cancer: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Pharmaceutical therapy drug name: Taxotere.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,092 days; disease-specific survival: no event (censored), 1,092 days; disease-free interval: no event (censored), 1,092 days; progression-free interval: no event (censored), 1,092 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BK-A0CB-01A-32D-A102-01): tumor purity 0.67, ploidy 2, whole-genome doublings 0.
